Gene-level copy-number profile of tumor specimen TCGA-D1-A16I-01A from TCGA case TCGA-D1-A16I, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: High Grade; Age at diagnosis: 62.5 years (22,836 days).
Specimen TCGA-D1-A16I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.1079ecf6-e788-4778-be30-d26b0193f4d9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A16I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/240b0078-cb6d-422a-9317-0194a27288f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 15,892; copy number 2: 31,836; copy number 3: 7,846; copy number 4: 3,337; copy number 5: 559; copy number 6: 51; copy number 7: 266.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A16I-01A-11D-A12G-01): tumor purity 0.87, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,055,901–168,137,667, 2 genes (within-gene range 0–1): GCSHP5, GPR161.
- chr3:116,850,277–117,027,039, 5 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr22:46,039,907–46,113,928, 11 genes: LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 876 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,635,238–44,986,722, 23 genes, copy number 5 (within-gene range 4–5): TMEM53, ARMH1, RNU5F-1, RNU5D-1, KIF2C, AL592166.1, RPS8, SNORD55, SNORD46, SNORD38A, SNORD38B, SNORD38B, RPS15AP11, BEST4, PLK3, TCTEX1D4, BTBD19, PTCH2, RNU5E-6P, AL136380.1, EIF2B3, RNA5SP47, CCNB1IP1P1.
- chr1:46,303,698–46,743,133, 18 genes, copy number 5: UQCRH, NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1.
- chr1:154,376,966–154,678,345, 15 genes, copy number 5: AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1, SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1.
- chr1:234,724,042–248,919,946, 337 genes, copy number 5 (broad region; genes not listed).
- chr9:87,741,233–87,837,225, 5 genes, copy number 6 (within-gene range 2–6): AL160279.1, CTSL3P, AL772337.4, FBP2P1, ELF2P3.
- chr9:129,503,461–129,722,674, 7 genes, copy number 5 (within-gene range 3–5): AL391056.2, AL391056.1, NTMT1, C9orf50, ASB6, AL590369.1, PRRX2.
- chr9:132,944,000–133,351,426, 22 genes, copy number 5: GFI1B, MIR548AW, AL593851.1, RNU7-21P, EEF1A1P5, GTF3C5, MIR6877, CEL, CELP, RALGDS, AL162417.1, GBGT1, OBP2B, LCN1P1, ABO, Y_RNA, LCN1P2, SURF6, Y_RNA, MED22, AL772161.1, RPL7A.
- chr11:47,400,970–47,449,143, 4 genes, copy number 5: MIR4487, SLC39A13, PSMC3, RAPSN.
- chr11:87,037,844–87,328,824, 1 gene, copy number 5 (within-gene range 1–5): TMEM135.
- chr11:87,258,851–88,524,054, 27 genes, copy number 5: AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P, U6, LINC02711, AP000756.1, MTCYBP41, AP000676.2, AP000676.3, AP000676.5, AP000676.4, AP000676.1, AP005436.3, AP005436.1, AP005436.2, Y_RNA, RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70, AP003120.1, GRM5-AS1.
- chr11:88,612,805–88,612,911, 1 gene, copy number 5: RNU6-16P.
- chr12:12,660,890–12,722,369, 4 genes, copy number 6: GPR19, AC008115.2, CDKN1B, AC008115.3.
- chr14:21,841,240–22,482,959, 52 genes, copy number 5 (within-gene range 3–5): TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.
- chr14:22,829,879–23,560,778, 51 genes, copy number 5: MRPL52, MMP14, Y_RNA, Y_RNA, LRP10, REM2, RBM23, PRMT5-AS1, PRMT5, AL132780.1, HAUS4, AL132780.3, MIR4707, AJUBA, AL132780.2, C14orf93, AL132780.5, PSMB5, AL132780.4, PSMB11, CDH24, ACIN1, C14orf119, LMLN2, CEBPE, SLC7A8, RNU6-1138P, RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2, THTPA.
- chr14:96,204,844–96,263,929, 1 gene, copy number 6 (within-gene range 4–6): AL355102.2.
- chr14:96,233,431–96,681,827, 15 genes, copy number 6: AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA, AL137786.1, RN7SKP108, AL137786.2.
- chr14:103,797,272–106,875,071, 266 genes, copy number 7 (broad region; genes not listed).
- chr18:22,200,619–22,228,029, 2 genes, copy number 5–6: AC091588.3, AC091588.2.
- chr19:12,284,337–12,640,098, 25 genes, copy number 6 (within-gene range 4–6): AC012618.2, ZNF563, ZNF442, RPS29P23, AC008758.4, AC008758.3, ZNF799, AC008758.5, ZNF443, AC008758.6, AC008758.2, ZNF709, AC008758.1, MTND2P40, MTCO1P27, MTCO2P27, MTATP6P27, PPIAP20, ZNF564, AC010422.6, AC010422.4, AC010422.1, PGK1P2, ZNF490, ZNF791.

Autosomal genes at a single copy (total copy number 1): 13,868. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
